Gene-level copy-number profile of tumor specimen C3L-02841-01 from CPTAC case C3L-02841, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 60.3 years (22,011 days).
Specimen C3L-02841-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 77860a71-2d23-43a2-a0ae-394a94306faa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02841-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/690a82fb-b06e-42c4-9955-9a057c94f842

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 4; copy number 2: 8,494; copy number 3: 832; copy number 4: 46,076; copy number 5: 2,241; copy number 6: 1,124; copy number 7: 22.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:1,971,153–1,976,478, 2 genes (within-gene range 0–2): AC019257.1, KBTBD11-OT1.
- chr8:1,974,818–1,975,314, 1 gene (within-gene range 0–2): AC019257.2.
- chr14:21,868,839–22,552,156, 115 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
